Surgical pathology report (de-identified scan), TCGA case TCGA-32-4719, project TCGA-GBM (Glioblastoma Multiforme), tissue source site St. Joseph's Hospital (AZ), specimen TCGA-32-4719-01A (Primary Tumor).

NEUROPATHOLOGY REPORT

SPECIMEN SOURCE:

1. Temporal lobe tumor
2. Temporal lobe tumor

CLINICAL DIAGNOSIS:

Left temporal lobe lesion

GROSS DESCRIPTION:

1. Received fresh for frozen section are two fragments of tan-pink soft tissue measuring 0.3 x 0.2 x 0.2 cm and 0.5 x 0.3 x 0.2 cm. A smear preparation is performed. Entirely frozen on one chuck.

FROZEN SECTION DIAGNOSIS:

CONSISTENT WITH HIGH GRADE ASTROCYTOMA.

The remainder of the previously frozen soft tissue is subsequently submitted for permanent section.

2. Received in formalin labeled with the patient's name and "temporal lobe tumor" are three fragments of tan-pink soft tissue ranging from 1.7 to 3.0 cm in greatest dimension and aggregating to 3.3 x 3.0 x 1.0 cm. The specimen is serially sectioned. Representative sections comprising approximately 60% of the specimen are submitted in three cassettes.

MICROSCOPIC DESCRIPTION:

- 1,2. Microscopic examination reveals a markedly hypercellular high grade glial neoplasm. The tumor consists of a proliferation of neoplastic cells with predominantly oval nuclei and prominent fibrillary processes. The tumor cells demonstrate significant atypia, including prominent nuclear pleomorphism and enlarged hyperchromatic nuclei. Scattered mitotic figures are seen. Necrosis, including early pseudopalisading necrosis is present, as well as robust microvascular proliferation. The neoplastic cells diffusely infiltrate the brain parenchyma. Numerous thrombosed blood vessels are seen. Overall, the histologic features are most consistent with a glioblastoma.

NEUROPATHOLOGY REPORT

DIAGNOSIS:

- (1,2) TEMPORAL LOBE TUMOR, BIOPSY AND RESECTION:
GLIOBLASTOMA (WHO GRADE IV).

CPT: 88307 x 2, 88331

Dictated by:

Verified by:

(Electronic Signature on

Source: NCI Genomic Data Commons file 41e61e75-74a6-43e7-bce8-328691173bb4 (TCGA-32-4719.3352B153-886C-413C-A704-E66CD4DC39BC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).